Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8284, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8284-01A (Primary Tumor).

[page 1 of 2]
d Case ID	Gross Description	Microscopic Description	Diagnosis Details	Comments	Formatted Path Report
					STOMACH TISSUE CHECKLIST Specimen type: Excision of tumor Tumor site: Antrum Tumor size: 8 x 7 x 2 cm Tumor features: None specified Histologic type: Adenocarcinoma, intestinal type Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - Lesser omentum Lymph nodes: 9/9 positive for metastasis (Intraabdominal 9/9) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: HER2/NEU-negative

[page 2 of 2]
ca ID		Excision date	Laterality

Source: NCI Genomic Data Commons file a9953b31-4be7-4898-9e5b-b2a4fc9d0c1f (TCGA-BR-8284.4EDF3F69-E07B-41E6-A040-31F950AD63CF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).